Gene-level copy-number profile of specimen HCM-BROD-0650-C56-85N from HCMI case HCM-BROD-0650-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; Tumor grade: High Grade; Age at diagnosis: 67.2 years (24,542 days).
Specimen HCM-BROD-0650-C56-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 076ea58a-b426-4b2a-bf96-f04cbbae4e14.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0650-C56-12A (saliva); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/7d5ee025-7a00-4a25-b0c1-3b8b2504ff58

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5,568; copy number 2: 21,904; copy number 3: 24,613; copy number 4: 5,140; copy number 5: 917; copy number 6: 170; copy number 7: 13; copy number 8: 61.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 74 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,960,121–181,847,885, 63 genes, copy number 7–8 (broad region; genes not listed).
- chr3:181,952,343–182,536,772, 7 genes, copy number 7: LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995.
- chr15:20,916,686–20,970,215, 4 genes, copy number 8: NF1P1, MIR5701-1, OR11J2P, OR11J5P.

Autosomal genes at a single copy (total copy number 1): 3,354. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
